Somatic mutation profile of tumor specimen C3N-02224-02 (aliquot CPT0214120006) from CPTAC case C3N-02224, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Tumor grade: G2.
Specimen C3N-02224-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4281821f-a6e8-45e1-941d-d8f7816afddb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02224-71 (Blood Derived Normal), aliquot CPT0214230002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cbe3e627-dc44-4d8d-b5d4-aeea498b35be

The open-access MAF lists 39 somatic variants for this specimen: 22 protein-altering or splice-affecting, 10 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 10, Frame Shift Del 4, Intron 3, 5'UTR 2, RNA 2, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID2 | c.3724A>C p.I1242L | Missense Mutation (SNP) | VAF 75/337 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.952); catalogued as COSV57600693; called by muse, mutect2, varscan2
- EPHA3 | c.289G>T p.V97L | Missense Mutation (SNP) | VAF 57/206 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV60695257; called by muse, mutect2, varscan2
- MTOR | c.7259C>T p.A2420V | Missense Mutation (SNP) | VAF 39/271 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63872793; called by muse, mutect2, varscan2
- RTL9 | c.3010T>C p.S1004P | Missense Mutation (SNP) | VAF 114/398 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71825837; called by muse, mutect2, varscan2
- SPICE1 | c.1402G>A p.G468R | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as rs139574129; called by muse, mutect2, varscan2
- VHL | c.259del p.V87Yfs*72 | Frame Shift Del (DEL) | VAF 217/706 reads (31%) | catalogued as COSV56551300, COSV56571580; called by mutect2, pindel, varscan2
- ZNF576 | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 150/589 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as rs760666894; called by muse, varscan2
- AGO3 | c.854dup p.T286Nfs*61 | Frame Shift Ins (INS) | VAF 22/207 reads (11%) | called by mutect2, pindel, varscan2
- APC2 | c.710A>C p.E237A | Missense Mutation (SNP) | VAF 57/418 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- BSPRY | c.89G>A p.S30N | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAAF5 | c.1810C>A p.H604N | Missense Mutation (SNP) | VAF 76/239 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- EREG | c.148G>C p.A50P | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GGA3 | c.1453del p.S485Lfs*39 (on ENST00000537686 / NM_138619.4; = p.S452Lfs*39 on NM_014001.5) | Frame Shift Del (DEL) | VAF 83/348 reads (24%) | called by mutect2, pindel, varscan2
- LHCGR | c.1358C>A p.S453Y | Missense Mutation (SNP) | VAF 73/267 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PBRM1 | c.974del p.N325Ifs*37 | Frame Shift Del (DEL) | VAF 44/193 reads (23%) | called by mutect2, pindel, varscan2
- PDSS2 | c.256A>C p.K86Q | Missense Mutation (SNP) | VAF 87/234 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PGLYRP2 | c.1731_*14delinsT | Nonstop Mutation (DEL) | VAF 10/64 reads (16%) | called by pindel, varscan2*
- TENM4 | c.3131A>T p.E1044V | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- THEM6 | c.293C>A p.T98K | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.109); called by muse, mutect2
- TMED10 | c.616T>A p.F206I | Missense Mutation (SNP) | VAF 78/323 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- TTN | c.51226del p.T17076Pfs*27 (on ENST00000591111; = p.T9652Pfs*27 on NM_003319.4) | Frame Shift Del (DEL) | VAF 9/80 reads (11%) | called by mutect2, pindel, varscan2
- ZNF576 | c.322G>C p.A108P | Missense Mutation (SNP) | VAF 146/584 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.102); called by muse, varscan2
- COL11A2 | c.516C>A p.T172= | Silent (SNP) | VAF 66/461 reads (14%) | called by muse, mutect2, varscan2
- LRRC3 | c.348G>T p.R116= | Silent (SNP) | VAF 36/229 reads (16%) | called by muse, mutect2, varscan2
- LYPD3 | c.537G>A p.L179= | Silent (SNP) | VAF 9/244 reads (4%) | called by muse, mutect2
- MEGF10 | c.1470A>C p.T490= | Silent (SNP) | VAF 75/286 reads (26%) | catalogued as COSV57244852; called by muse, mutect2, varscan2
- PPP4R4 | c.1837C>T p.L613= | Silent (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- PRR3 | c.342C>G p.G114= | Silent (SNP) | VAF 50/183 reads (27%) | called by muse, mutect2, varscan2
- PRRC2B | c.5412T>C p.G1804= | Silent (SNP) | VAF 146/556 reads (26%) | called by muse, mutect2, varscan2
- SEMA3A | c.348T>C p.N116= | Silent (SNP) | VAF 55/219 reads (25%) | called by muse, mutect2, varscan2
- STRBP | c.1794A>C p.T598= | Silent (SNP) | VAF 79/275 reads (29%) | called by muse, mutect2, varscan2
- ZFP82 | c.1290C>G p.A430= | Silent (SNP) | VAF 73/294 reads (25%) | called by muse, mutect2, varscan2
- AC139795.1 | n.1669_1674del | RNA (DEL) | VAF 94/358 reads (26%) | called by mutect2, varscan2
- AFF1 | c.1038+2157G>A | Intron (SNP) | VAF 43/303 reads (14%) | catalogued as rs1054696099, COSV100321215; called by muse, mutect2, varscan2
- ANKRD26P1 | n.1928A>G | RNA (SNP) | VAF 24/248 reads (10%) | called by muse, mutect2
- AQP8 | c.-3C>A | 5'UTR (SNP) | VAF 55/283 reads (19%) | called by muse, mutect2, varscan2
- OSMR-AS1 | n.126+23677A>G | Intron (SNP) | VAF 8/16 reads (50%) | catalogued as rs757872267; called by muse, varscan2
- PRDM11 | c.656+4256G>A | Intron (SNP) | VAF 135/490 reads (28%) | catalogued as rs1434978719; called by muse, mutect2, varscan2
- ZNF620 | c.-41C>T | 5'UTR (SNP) | VAF 59/422 reads (14%) | catalogued as rs1227958880, COSV100094177; called by muse, varscan2
